Gene-level copy-number profile of tumor specimen TCGA-EK-A2RK-01A from TCGA case TCGA-EK-A2RK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IA2; Tumor grade: G3; Age at diagnosis: 67.2 years (24,541 days).
Specimen TCGA-EK-A2RK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.bbcba02a-f37e-4f6a-a973-b19e6c11ff31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2RK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6078c74b-86b4-4551-99f5-97814337c6c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21,691; copy number 2: 35,406; copy number 3: 2,723.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2RK-01A-11D-A18H-01): tumor purity 0.78, ploidy 1.68, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 21,691. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
